Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8114, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8114-01A (Primary Tumor).

Tumor: [REDACTED]
Control: [REDACTED]

Diagnosis- Anaplastic Oligoastrocytoma
MIB-1 Labeling Index= 5.2%

Microscopic description:

Sections demonstrate a moderately to markedly hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. The tumor demonstrates several distinct regional patterns. These include regions with a predominant phenotype. The majority of these appear to be ordinary gemistocytes but some microgemistocytes are also noted. In other areas a fibrillary or protoplasmic astrocytoma phenotype predominates. Finally, a microcystic stroma is focally prominent. Although nuclei tend to be round, and some have few processes, classic oligodendroglioma differentiation is not seen. Atypia ranges from mild to marked with the latter regionally present as scattered large, often multinucleated cells. Mitoses are rare with never more than 2 mitoses per 10 high power fields. Microvascular proliferation is not seen but there is focal tumor necrosis.

Source: NCI Genomic Data Commons file c1abdc5e-6084-4a06-9aa7-f96ea05e9563 (TCGA-HT-8114.8AA9D827-A738-4750-AF50-C0886CC64AEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).